FM case AD5163 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/763eaaed-a799-4dcb-a834-de1a536243dd

Male, 75.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
